TCGA case TCGA-BP-4334 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e5eca191-f585-490d-81e3-9cced1047093

Demographics
Sex at birth: male; Race: white; Age at index: 56 years; Vital status: Dead; Days to death: 645 days (1.8 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 56.4 years (20,609 days); Year of diagnosis: 2003; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Palliative; Days to treatment start: 483 days (1.3 years); Days to treatment end: 483 days (1.3 years); Treatment dose: 1,800 cGy; Course number: 1; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Initial disease status: Progressive Disease; Days to treatment start: 520 days (1.4 years); Route of administration: Subcutaneous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 57.6 years (21,051 days); Days to diagnosis: 442 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 442 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 645 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 645 days (1.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Low.
- Platelets: Normal.
- Calcium: Low.
- Leukocytes: Elevated.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4334-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 1.2; Shortest dimension: 0.3.
  Slide TCGA-BP-4334-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-BP-4334-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-BP-4334-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4334-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.2; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Drug treatment: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: SC.
- Radiation treatment: Radiation type other: sterotactic radiosurgery.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: Case possible Kidney Chromophobe.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 645 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 645 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 442 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BP-4334-01): tumor purity 0.86, ploidy 1.62, whole-genome doublings 0 (call status: legacy_call).
